CCDI case PBBPBJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3cd2f329-e09e-4867-9835-e87b7f760709

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.5 years (6,010 days).

Biospecimens (3 samples)
- Sample 0DDNCV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDNCY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDNCZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
